Somatic mutation profile of tumor specimen 0DPCY6 from CCDI case PBCBDY, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Rhabdomyosarcoma, NOS; Tissue or organ of origin: Testis, NOS; Age at diagnosis: 19.3 years (7,035 days).
Specimen 0DPCY6: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 944ee8ba-815c-431a-a064-af125d88e9f3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DPCXP (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9bedb3b8-df90-40dc-8008-18ca97319ca0

The open-access MAF lists 75 somatic variants for this specimen: 52 protein-altering or splice-affecting, 13 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 47, Silent 13, Intron 7, Nonsense Mutation 3, 5'UTR 2, Splice Region 1, Splice Site 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AMZ1 | c.214G>A p.E72K | Missense Mutation (SNP) | VAF 39/334 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.335); catalogued as rs543403758; called by muse, mutect2, varscan2
- BBX | c.1859A>G p.Y620C | Missense Mutation (SNP) | VAF 104/570 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57881898; called by muse, mutect2, varscan2
- BCAN | c.355G>A p.D119N | Missense Mutation (SNP) | VAF 18/290 reads (6%) | SIFT tolerated (0.11); PolyPhen probably damaging (1); catalogued as COSV61256048; called by muse, mutect2
- CCT2 | c.1308G>T p.M436I | Missense Mutation (SNP) | VAF 966/6114 reads (16%) | SIFT tolerated (0.98); PolyPhen benign (0.021); catalogued as COSV100167805; called by mutect2, varscan2
- CHCHD2 | c.247G>A p.G83S | Missense Mutation (SNP) | VAF 67/583 reads (11%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.486); catalogued as rs1554374857; called by muse, mutect2, varscan2
- CPAMD8 | c.4594G>A p.G1532S (on ENST00000651564; = p.G1485S on NM_015692.5) | Missense Mutation (SNP) | VAF 37/355 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750931832; called by muse, mutect2, varscan2
- DMXL2 | c.6377G>T p.R2126L | Missense Mutation (SNP) | VAF 136/618 reads (22%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.991); catalogued as COSV51857421; called by mutect2, varscan2
- DNAH5 | c.10192C>T p.R3398C | Missense Mutation (SNP) | VAF 119/963 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs147882360; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EGFR | c.628C>T p.L210= | Splice Region (SNP) | VAF 76/690 reads (11%) | catalogued as COSV51837150; called by muse, mutect2, varscan2
- EML6 | c.3475C>T p.R1159W | Missense Mutation (SNP) | VAF 365/659 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs1031492352, COSV100728316, COSV62864772; called by muse, mutect2, varscan2
- FCGBP | c.2573C>T p.P858L | Missense Mutation (SNP) | VAF 23/232 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs759479871; called by muse, mutect2, varscan2
- GPR31 | c.358C>T p.R120W | Missense Mutation (SNP) | VAF 49/275 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs774440089; called by muse, mutect2, varscan2
- MAVS | c.128G>A p.R43Q | Missense Mutation (SNP) | VAF 26/290 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs759224829; called by muse, mutect2
- NELL2 | c.1661C>T p.T554M | Missense Mutation (SNP) | VAF 195/691 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.828); catalogued as rs200918496, COSV61569411; called by muse, mutect2, varscan2
- NOD2 | c.1285G>T p.A429S | Missense Mutation (SNP) | VAF 74/346 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.34); catalogued as COSV56049757; called by muse, mutect2, varscan2
- PAK1 | c.772C>T p.R258* | Nonsense Mutation (SNP) | VAF 72/452 reads (16%) | catalogued as rs201726311, COSV53695751; called by muse, mutect2, varscan2
- PCDH15 | c.5168C>G p.P1723R | Missense Mutation (SNP) | VAF 111/546 reads (20%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.095); catalogued as COSV100214727; called by muse, mutect2, varscan2
- PROS1 | c.476A>T p.N159I | Missense Mutation (SNP) | VAF 155/418 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV62397979; called by muse, mutect2, varscan2
- RGL4 | c.869G>A p.R290Q | Missense Mutation (SNP) | VAF 36/214 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.028); catalogued as rs145535096; called by muse, mutect2, varscan2
- SAFB | c.2282C>T p.S761L | Missense Mutation (SNP) | VAF 38/346 reads (11%) | SIFT tolerated (0.7); PolyPhen benign (0.015); catalogued as rs1364617860; called by muse, mutect2, varscan2
- SHANK3 | c.775C>T p.R259C | Missense Mutation (SNP) | VAF 25/171 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV99436773; called by muse, mutect2, varscan2
- SYBU | c.365G>C p.G122A (on ENST00000276646 / NM_001099754.2; = p.G121A on NM_017786.6) | Missense Mutation (SNP) | VAF 150/1275 reads (12%) | SIFT tolerated (0.72); PolyPhen benign (0.029); catalogued as rs779585365; called by muse, mutect2, varscan2
- TRMT1 | c.1498C>T p.R500C | Missense Mutation (SNP) | VAF 54/387 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1042996697; called by muse, mutect2, varscan2
- ABHD12B | c.456-1G>C p.X152_splice (on ENST00000337334 / NM_001206673.2; = p.X75_splice on NM_181533.3 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 18/165 reads (11%) | called by muse, mutect2, varscan2
- ANK3 | c.2195C>T p.T732I | Missense Mutation (SNP) | VAF 128/619 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ASPM | c.2072A>T p.Y691F | Missense Mutation (SNP) | VAF 37/1449 reads (3%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.6); called by muse, mutect2
- BAZ1B | c.455C>A p.S152Y | Missense Mutation (SNP) | VAF 122/1015 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.687); called by muse, mutect2, varscan2
- DNAH5 | c.12896T>C p.L4299P | Missense Mutation (SNP) | VAF 93/552 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- EXOC2 | c.1197C>G p.N399K | Missense Mutation (SNP) | VAF 95/529 reads (18%) | SIFT tolerated (0.92); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- IGSF9 | c.1630A>T p.T544S (on ENST00000368094 / NM_001135050.2; = p.T528S on NM_020789.4) | Missense Mutation (SNP) | VAF 16/283 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0.019); called by muse, mutect2
- IL7 | c.358C>A p.Q120K | Missense Mutation (SNP) | VAF 175/1368 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- KRT2 | c.967C>A p.Q323K | Missense Mutation (SNP) | VAF 36/582 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); called by muse, mutect2
- LMNTD1 | c.592A>T p.M198L | Missense Mutation (SNP) | VAF 32/1159 reads (3%) | SIFT tolerated (0.1); PolyPhen benign (0.023); called by muse, mutect2
- LONRF2 | c.770C>G p.A257G | Missense Mutation (SNP) | VAF 363/777 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- MCMBP | c.187A>T p.N63Y | Missense Mutation (SNP) | VAF 56/878 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- MOCOS | c.1335G>T p.Q445H | Missense Mutation (SNP) | VAF 37/191 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- MSANTD1 | c.199C>A p.Q67K | Missense Mutation (SNP) | VAF 29/131 reads (22%) | SIFT tolerated (0.8); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- NELL2 | c.688A>G p.T230A | Missense Mutation (SNP) | VAF 139/1125 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- PLCH1 | c.2176C>A p.L726I (on ENST00000340059 / NM_001130960.2; = p.L738I on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 146/738 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.749); called by muse, mutect2, varscan2
- PPIE | c.227C>A p.T76K | Missense Mutation (SNP) | VAF 250/575 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- RABAC1 | c.116G>T p.R39L | Missense Mutation (SNP) | VAF 39/334 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- RIIAD1 | c.179G>T p.R60I | Missense Mutation (SNP) | VAF 211/448 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RRH | c.700G>T p.D234Y | Missense Mutation (SNP) | VAF 20/470 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.156); called by muse, mutect2
- RTL9 | c.2555C>G p.S852C | Missense Mutation (SNP) | VAF 60/172 reads (35%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- RYR2 | c.7720C>A p.L2574I | Missense Mutation (SNP) | VAF 84/748 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.576); called by muse, varscan2
- SRRT | c.1093G>A p.G365S | Missense Mutation (SNP) | VAF 63/535 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- SYNE2 | c.13355G>A p.W4452* | Nonsense Mutation (SNP) | VAF 99/450 reads (22%) | called by muse, mutect2, varscan2
- TEX13A | c.938A>G p.D313G | Missense Mutation (SNP) | VAF 94/157 reads (60%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- TJAP1 | c.1410G>T p.L470F (on ENST00000372445 / NM_001146016.1; = p.L460F on NM_080604.3) | Missense Mutation (SNP) | VAF 41/209 reads (20%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.387); called by muse, mutect2, varscan2
- TNPO3 | c.2735G>T p.C912F | Missense Mutation (SNP) | VAF 38/760 reads (5%) | SIFT tolerated (0.73); PolyPhen benign (0.024); called by muse, mutect2
- TRIM49 | c.104G>T p.C35F | Missense Mutation (SNP) | VAF 54/275 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by mutect2, varscan2
- XPO5 | c.322G>T p.E108* | Nonsense Mutation (SNP) | VAF 102/591 reads (17%) | called by muse, mutect2, varscan2
- CCDC141 | c.3417C>T p.D1139= | Silent (SNP) | VAF 340/1140 reads (30%) | called by muse, mutect2, varscan2
- CHMP7 | c.939T>C p.Y313= | Silent (SNP) | VAF 47/415 reads (11%) | called by muse, mutect2, varscan2
- GBP3 | c.18C>T p.H6= | Silent (SNP) | VAF 21/577 reads (4%) | called by muse, mutect2
- GPR34 | c.1068T>C p.T356= | Silent (SNP) | VAF 188/635 reads (30%) | catalogued as rs146248981; called by muse, mutect2, varscan2
- HDAC11 | c.129C>A p.G43= | Silent (SNP) | VAF 66/333 reads (20%) | called by muse, mutect2, varscan2
- MUC16 | c.30714G>A p.T10238= | Silent (SNP) | VAF 56/676 reads (8%) | catalogued as rs376564075; called by muse, mutect2
- NDUFS1 | c.969C>G p.L323= | Silent (SNP) | VAF 135/718 reads (19%) | catalogued as rs369091692; called by muse, mutect2, varscan2
- RABAC1 | c.117C>T p.R39= | Silent (SNP) | VAF 39/336 reads (12%) | catalogued as COSV55771483; called by muse, mutect2, varscan2
- RNPC3 | c.153G>C p.G51= | Silent (SNP) | VAF 124/724 reads (17%) | catalogued as COSV68433821; called by muse, mutect2, varscan2
- RSPO2 | c.333C>A p.T111= | Silent (SNP) | VAF 389/1584 reads (25%) | called by muse, mutect2, varscan2
- SDCBP2 | c.633G>A p.K211= (on ENST00000339987 / NM_001199784.1; = p.K126= on NM_015685.5) | Silent (SNP) | VAF 67/386 reads (17%) | called by muse, mutect2, varscan2
- SIK3 | c.3777G>A p.T1259= (on ENST00000445177 / NM_001366686.2; = p.T1217= on NM_025164.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 72/313 reads (23%) | catalogued as rs753013100; called by muse, mutect2, varscan2
- SLC5A8 | c.1617C>T p.V539= | Silent (SNP) | VAF 96/652 reads (15%) | called by muse, varscan2
- CTSB | c.677-21C>T | Intron (SNP) | VAF 47/523 reads (9%) | catalogued as rs368086362; called by muse, mutect2
- CYP27B1 | c.196-58G>T | Intron (SNP) | VAF 14/128 reads (11%) | called by muse, mutect2
- ERCC8 | c.550+65C>T | Intron (SNP) | VAF 68/1080 reads (6%) | called by muse, mutect2
- KRT79 | c.-15G>A | 5'UTR (SNP) | VAF 47/330 reads (14%) | catalogued as rs370509343; called by muse, mutect2, varscan2
- LIF | chr22:30240268 C>T | 3'Flank (SNP) | VAF 14/105 reads (13%) | called by muse, mutect2
- MAGEB4 | c.-34A>G | 5'UTR (SNP) | VAF 20/336 reads (6%) | called by muse, mutect2
- RADIL | c.1417-15G>A | Intron (SNP) | VAF 20/224 reads (9%) | catalogued as rs138344344; called by muse, mutect2, varscan2
- SAPCD1 | c.256-52G>A | Intron (SNP) | VAF 12/65 reads (18%) | called by mutect2, varscan2
- TDRD9 | c.3975-8del | Intron (DEL) | VAF 26/120 reads (22%) | catalogued as rs3831000; called by mutect2, varscan2
- TTN | c.10303+1157C>G | Intron (SNP) | VAF 135/869 reads (16%) | called by muse, mutect2, varscan2
